Somatic mutation profile of tumor specimen TCGA-22-4605-01A (aliquot TCGA-22-4605-01A-21D-2122-08) from TCGA case TCGA-22-4605, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 78.4 years (28,623 days).
Specimen TCGA-22-4605-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1fa7584-c172-4ce2-9de1-220b5c0b59e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4605-11A (Solid Tissue Normal), aliquot TCGA-22-4605-11A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddeed873-5f8e-45cf-b89d-d94c44dfcd87

The open-access MAF lists 93 somatic variants for this specimen: 73 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 18, Splice Site 3, In Frame Del 1, RNA 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.919+1G>T p.X307_splice | Splice Site (SNP) | VAF 19/73 reads (26%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13319G>T p.G4440V | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101291268; called by muse, mutect2
- ARHGAP31 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs886057800, COSV99957284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF10L | c.3785C>T p.P1262L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1472326688, COSV51429525, COSV99392434; called by muse, mutect2, varscan2
- ATP2B1 | c.3421A>T p.I1141F | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99665407; called by muse, mutect2
- ATP7A | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV100430533; called by muse, mutect2, varscan2
- BTBD9 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs150015110, COSV58426603; called by muse, mutect2, varscan2
- CCNI | c.114+2T>C p.X38_splice | Splice Site (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99423309; called by muse, mutect2
- CDH10 | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV52576167; called by muse, mutect2, varscan2
- CERT1 | c.977A>G p.K326R (on ENST00000405807 / NM_001130105.1; = p.K198R on NM_005713.3) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV99783048; called by muse, mutect2, varscan2
- CLEC4F | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as COSV99713651, COSV99714019; called by muse, mutect2, varscan2
- CLPP | c.555+1G>A p.X185_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99832152; called by muse, mutect2, varscan2
- COL12A1 | c.8029G>C p.A2677P | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100485672; called by muse, mutect2, varscan2
- COLGALT1 | c.1805G>T p.R602L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.051); catalogued as COSV99394918; called by muse, mutect2, varscan2
- DGKI | c.1457T>G p.L486R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99933226; called by muse, mutect2, varscan2
- EHBP1 | c.2084T>C p.L695S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs1362945392, COSV99860444; called by muse, mutect2, varscan2
- EPB41L5 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99758464; called by muse, mutect2
- EVX2 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV100420621; called by muse, mutect2, varscan2
- FAT1 | c.12551G>T p.G4184V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV101499197, COSV71672441; called by muse, mutect2, varscan2
- FBN3 | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs756791031, COSV99560404; called by muse, mutect2, varscan2
- FGA | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.229); catalogued as COSV100120244; called by muse, mutect2, varscan2
- FYB1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs757886197, COSV60940974; called by muse, mutect2
- GAP43 | c.596C>A p.T199N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV100525428; called by muse, mutect2, varscan2
- GPR61 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV101344401; called by muse, mutect2
- HELB | c.2641G>T p.A881S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV99921705; called by muse, mutect2, varscan2
- HIP1 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1418876899, COSV61192438; called by muse, mutect2, varscan2
- HLA-G | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100827033; called by muse, mutect2, varscan2
- HNRNPDL | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV99787041; called by muse, mutect2, varscan2
- KALRN | c.2087A>G p.N696S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.992); catalogued as rs757760603, COSV99563093; called by muse, mutect2, varscan2
- LRCH4 | c.644G>C p.R215P | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100052780, COSV59642105; called by muse, mutect2, varscan2
- LTA | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV101403162; called by muse, mutect2
- MAGEB4 | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100854641, COSV100854822; called by muse, mutect2, varscan2
- MOXD1 | c.1442C>A p.A481E | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60948210; called by muse, mutect2
- MSH5 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as rs200755245, COSV100991783; called by muse, mutect2, varscan2
- MUC21 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.194); catalogued as rs1360690049, COSV100888845; called by muse, varscan2
- MYO1D | c.1424T>G p.L475R | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV100553934; called by muse, mutect2, varscan2
- N4BP2 | c.2488A>G p.S830G | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99788396; called by muse, mutect2, varscan2
- NAALAD2 | c.1923A>G p.I641M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100428210; called by muse, mutect2, varscan2
- NCBP2 | c.184A>C p.K62Q | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV100051909; called by muse, mutect2, varscan2
- NPHP4 | c.4249G>A p.E1417K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs746775119, COSV100976805; called by muse, mutect2, varscan2
- OOEP | c.156C>A p.F52L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV100949801; called by muse, mutect2, varscan2
- OOEP | c.155T>A p.F52Y | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs541440333, COSV100949802; called by muse, mutect2, varscan2
- OR10G7 | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV100389830, COSV57865473, COSV57865543; called by muse, mutect2
- OR13C9 | c.476A>C p.Q159P | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV52243991, COSV99403393; called by muse, mutect2
- OR51M1 | c.231G>T p.L77F | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV100150185; called by muse, mutect2
- OR7C2 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV50181209, COSV99934469; called by muse, mutect2
- PCDHGC5 | c.1202A>G p.E401G | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.783); catalogued as COSV99338966, COSV99342138; called by muse, mutect2, varscan2
- PKD2L1 | c.712G>T p.G238W | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100559345; called by muse, mutect2, varscan2
- RIMS2 | c.2998C>A p.H1000N (on ENST00000666250 / NM_001348490.2; = p.H808N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV51683374, COSV99165259; called by muse, mutect2, varscan2
- RSPRY1 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327464943, COSV68027501; called by muse, mutect2, varscan2
- RTL9 | c.2381C>G p.S794C | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV101511654; called by muse, mutect2, varscan2
- SEC23IP | c.196T>C p.F66L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100956802; called by muse, mutect2
- SELE | c.1019T>C p.M340T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1212961431, COSV100324642; called by muse, mutect2, varscan2
- SF3B4 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.348); catalogued as COSV99641042; called by muse, mutect2, varscan2
- SLC17A6 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867231934, COSV99581137; called by muse, mutect2
- SLC38A11 | c.1075A>G p.M359V (on ENST00000409149 / NM_001351539.1; = p.M337V on NM_173512.2) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as COSV100366790; called by muse, mutect2
- SLCO1B3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53934561; called by muse, mutect2
- SLF2 | c.3406T>A p.Y1136N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99488784; called by muse, mutect2, varscan2
- SORCS3 | c.2467G>T p.G823C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746273764, COSV100863481; called by muse, mutect2, varscan2
- SPIN2A | c.605C>G p.P202R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs1462094748, COSV100888048; called by mutect2, varscan2
- STAT4 | c.1193A>T p.E398V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100635998; called by muse, mutect2, varscan2
- TCEAL6 | c.470A>C p.Q157P | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101035945; called by muse, mutect2
- TENT5B | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100006552; called by muse, mutect2, varscan2
- TINAG | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773894936, COSV52505354, COSV99449057; called by muse, mutect2, varscan2
- TNXB | c.8912C>T p.T2971M (on ENST00000647633; = p.T2724M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs768579099, COSV64478054; called by muse, mutect2, varscan2
- TXLNB | c.1906G>T p.A636S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV100624896; called by muse, mutect2, varscan2
- U2SURP | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.184); catalogued as COSV101204403; called by muse, mutect2
- UAP1 | c.1447A>G p.I483V (on ENST00000271469 / NM_001324116.1; = p.I466V on NM_003115.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV99617550; called by muse, mutect2, varscan2
- ZNF280A | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs748518449, COSV100130999; called by muse, mutect2, varscan2
- ZNF559 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV100416476; called by muse, mutect2
- MIS18BP1 | c.340dup p.I114Nfs*12 | Frame Shift Ins (INS) | VAF 10/87 reads (11%) | called by mutect2, pindel, varscan2
- PDGFRA | c.3126_3134del p.Q1043_S1045del | In Frame Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel, varscan2
- AK9 | c.495T>C p.N165= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV99572432; called by muse, mutect2, varscan2
- CEP128 | c.51G>A p.L17= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV53676015; called by muse, mutect2, varscan2
- ENPP3 | c.2355C>A p.T785= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV100716998; called by muse, mutect2
- KDM8 | c.792G>A p.V264= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs961970745, COSV99619360; called by muse, mutect2, varscan2
- MUC17 | c.1983C>A p.T661= | Silent (SNP) | VAF 53/497 reads (11%) | catalogued as COSV100072469; called by muse, mutect2, varscan2
- OR13G1 | c.39C>A p.G13= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100687144; called by muse, mutect2
- OR1S1 | c.33C>A p.G11= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV100515322; called by muse, mutect2, varscan2
- OR51A7 | c.123C>A p.G41= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV100834627; called by muse, mutect2
- PRTG | c.2835A>G p.Q945= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs746301981, COSV101221333; called by muse, mutect2, varscan2
- PSD3 | c.2937C>T p.T979= (on ENST00000440756; = p.T978= on NM_015310.4) | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as rs1226015728, COSV99675583; called by muse, mutect2
- SBF2 | c.1437G>C p.R479= | Silent (SNP) | VAF 17/175 reads (10%) | catalogued as COSV99813733; called by muse, mutect2, varscan2
- SHANK2 | c.3219C>T p.T1073= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs139289007; called by muse, mutect2
- SHH | c.402C>T p.H134= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1223316650, COSV51918252, COSV99793329; called by muse, mutect2, varscan2
- SMARCAD1 | c.48G>A p.K16= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV100758846; called by muse, mutect2
- SORBS1 | c.2832C>T p.S944= (on ENST00000361941 / NM_001034954.2; = p.S594= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV99527683; called by muse, mutect2, varscan2
- TMEM39B | c.1008G>A p.Q336= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100297942; called by muse, mutect2, varscan2
- TREML1 | c.213T>A p.A71= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100632563; called by mutect2, varscan2
- TRPM2 | c.3909G>A p.V1303= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100308457; called by muse, mutect2, varscan2
- CYP11B1 | c.240-170A>T | Intron (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99454857; called by muse, mutect2, varscan2
- DCHS2 | n.3182G>T | RNA (SNP) | VAF 16/97 reads (16%) | catalogued as rs556229617, COSV100251367, COSV59733050; called by muse, mutect2, varscan2
